Somatic mutation profile of tumor specimen TCGA-DD-A1EI-01A (aliquot TCGA-DD-A1EI-01A-11D-A12Z-10) from TCGA case TCGA-DD-A1EI, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.8 years (17,097 days).
Specimen TCGA-DD-A1EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f10afc9-adeb-4883-bf82-3313cac90508.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EI-11A (Solid Tissue Normal), aliquot TCGA-DD-A1EI-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ea479e2-7c3c-4cf4-88d8-dc2d666c1d31

The open-access MAF lists 66 somatic variants for this specimen: 48 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 9, Intron 4, Frame Shift Del 3, Nonsense Mutation 3, RNA 2, 3'UTR 2, In Frame Ins 1, Frame Shift Ins 1, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1740del p.F580Lfs*4 | Frame Shift Del (DEL) | VAF 70/279 reads (25%) | catalogued as rs753829902; called by mutect2, pindel, varscan2
- AC011455.2 | c.1181G>T p.C394F | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV55499986; called by muse, mutect2, varscan2
- AK7 | c.498+1G>A p.X166_splice | Splice Site (SNP) | VAF 8/57 reads (14%) | catalogued as rs377123131; called by muse, mutect2, varscan2
- ARHGEF28 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV55258129; called by muse, mutect2, varscan2
- ASH1L | c.8627A>C p.N2876T (on ENST00000368346 / NM_001366177.2; = p.N2871T on NM_018489.3) | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV64208779; called by muse, mutect2, varscan2
- ASRGL1 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57124960; called by muse, mutect2, varscan2
- BCL11A | c.1124T>G p.L375R (on ENST00000335712 / NM_001365609.1; = p.L409R on NM_018014.4) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59631094; called by muse, mutect2, varscan2
- CD300LG | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs766697730, COSV53224088; called by muse, mutect2, varscan2
- CHTF18 | c.2683C>T p.H895Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV50210555; called by muse, mutect2, varscan2
- COL11A1 | c.926A>G p.Y309C | Missense Mutation (SNP) | VAF 63/416 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.339); catalogued as COSV62182301; called by muse, mutect2, varscan2
- CYP4Z1 | c.1097C>G p.T366R | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766692536, COSV61965158; called by muse, varscan2
- DCLRE1C | c.678G>A p.Q226= (on ENST00000378278 / NM_001350965.2; = p.Q111= on NM_022487.4) | Splice Region (SNP) | VAF 68/219 reads (31%) | catalogued as COSV63183766; called by muse, mutect2, varscan2
- DNAH1 | c.4453C>T p.Q1485* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as COSV70229805, COSV70230886; called by muse, mutect2, varscan2
- FLT3LG | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs1195581012, COSV52619333; called by muse, mutect2, varscan2
- IL12RB2 | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52023848; called by muse, mutect2, varscan2
- KCNJ8 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53716674; called by muse, mutect2, varscan2
- LNPEP | c.2446A>G p.M816V | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51478422; called by muse, mutect2, varscan2
- MAGEC1 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV53574044, COSV53577416; called by muse, mutect2, varscan2
- MICAL1 | c.2059C>T p.Q687* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as COSV57805557; called by muse, mutect2, varscan2
- MLXIPL | c.763A>G p.T255A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57667754, COSV57668508; called by muse, mutect2, varscan2
- MME | c.1882A>C p.N628H | Missense Mutation (SNP) | VAF 92/364 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64707868; called by muse, mutect2, varscan2
- MROH2B | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV68184941; called by muse, mutect2, varscan2
- MYO6 | c.2515G>A p.G839S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as rs1352587099, COSV64119369; called by muse, mutect2, varscan2
- NPFF | c.329T>C p.F110S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV57199666; called by muse, mutect2, varscan2
- NRXN1 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs369744946; called by muse, mutect2, varscan2
- OR5B12 | c.164C>A p.T55N | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV56905302; called by muse, mutect2, varscan2
- OSGIN2 | c.1511T>C p.I504T | Missense Mutation (SNP) | VAF 122/210 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV52408876; called by muse, varscan2
- PAX1 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV68272121; called by muse, mutect2, varscan2
- PCDH11Y | c.2666C>A p.P889Q (on ENST00000400457 / NM_032973.2; = p.P878Q on NM_032971.3) | Missense Mutation (SNP) | VAF 108/434 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53076897, COSV53082512; called by muse, mutect2, varscan2
- PTCD1 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV52857769; called by muse, mutect2, varscan2
- RBM48 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as COSV50399966; called by muse, mutect2, varscan2
- RBP5 | c.32T>A p.F11Y | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV56936866; called by muse, mutect2, varscan2
- SBNO1 | c.606A>C p.R202S (on ENST00000420886; = p.R201S on NM_018183.5) | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV57342316; called by muse, mutect2, varscan2
- SEMG2 | c.946A>T p.I316F | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV65647545; called by muse, mutect2, varscan2
- ST3GAL1 | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 164/306 reads (54%) | PolyPhen probably damaging (1); catalogued as COSV60613469; called by muse, mutect2, varscan2
- TBX2 | c.463A>T p.M155L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV53599297; called by muse, mutect2, varscan2
- TRPM7 | c.2890A>C p.I964L | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV57917176; called by muse, varscan2
- ZCCHC2 | c.3388A>C p.N1130H | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV54038229; called by muse, mutect2, varscan2
- ZNF365 | c.793G>T p.V265F | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV67925632; called by muse, mutect2, varscan2
- ZNF462 | c.2788T>C p.C930R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52940252; called by muse, mutect2
- ZNF596 | c.956G>A p.C319Y | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.308); catalogued as COSV57654171; called by muse, mutect2, varscan2
- ZNF687 | c.2815dup p.R939Pfs*36 | Frame Shift Ins (INS) | VAF 16/76 reads (21%) | catalogued as rs749403447; called by mutect2, varscan2
- ZP1 | c.1543T>G p.S515A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as COSV53924800; called by muse, mutect2
- C1orf68 | c.140del p.P47Lfs*10 | Frame Shift Del (DEL) | VAF 55/238 reads (23%) | called by mutect2, pindel, varscan2
- KCNT2 | c.2501_2506del p.S834_I835del | In Frame Del (DEL) | VAF 21/105 reads (20%) | called by mutect2, pindel, varscan2
- MINDY1 | c.413_415dup p.P138dup | In Frame Ins (INS) | VAF 56/243 reads (23%) | called by mutect2, pindel, varscan2
- SHROOM3 | c.4722_4726del p.K1576Dfs*17 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel, varscan2
- CD177 | c.1125A>G p.Q375= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as COSV65121493; called by muse, mutect2
- CECR2 | c.4065A>G p.A1355= (on ENST00000342247 / NM_001290047.2; = p.A1171= on NM_001290046.1) | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV52842690; called by muse, mutect2, varscan2
- KRCC1 | c.360T>C p.F120= | Silent (SNP) | VAF 129/475 reads (27%) | catalogued as COSV61251644; called by muse, mutect2, varscan2
- PHF21B | c.942C>T p.S314= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as rs762856929, COSV57558844; called by muse, mutect2, varscan2
- SLAMF6 | c.540T>C p.T180= | Silent (SNP) | VAF 65/224 reads (29%) | catalogued as rs1468068474, COSV63587300; called by muse, mutect2, varscan2
- SLITRK2 | c.600C>A p.G200= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs377679182, COSV59425894, COSV59427263; called by muse, mutect2, varscan2
- SPATA24 | c.6G>T p.A2= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV57474633, COSV57474750; called by muse, mutect2, varscan2
- TMEM106C | c.351C>T p.G117= | Silent (SNP) | VAF 46/743 reads (6%) | catalogued as COSV56742871; called by muse, mutect2
- TRHR | c.1182C>A p.S394= | Silent (SNP) | VAF 64/279 reads (23%) | catalogued as COSV100304840, COSV61234529; called by muse, mutect2, varscan2
- COL4A2 | c.1433-642G>A | Intron (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- LRP1B | c.13247+886C>T | Intron (SNP) | VAF 15/69 reads (22%) | catalogued as rs761015954, COSV67274995; called by muse, mutect2, varscan2
- NRP1 | c.1924+2133_1924+2150del | Intron (DEL) | VAF 19/121 reads (16%) | called by mutect2, pindel, varscan2
- RPL37AP1 | chr20:44465172 C>A | 3'Flank (SNP) | VAF 41/138 reads (30%) | called by muse, mutect2, varscan2
- SSPOP | n.3943G>A | RNA (SNP) | VAF 23/93 reads (25%) | catalogued as COSV50487797; called by muse, mutect2, varscan2
- TENT5D | c.*722T>C | 3'UTR (SNP) | VAF 57/213 reads (27%) | catalogued as COSV100382826; called by muse, mutect2, varscan2
- TNFSF15 | c.301+695G>C | Intron (SNP) | VAF 115/350 reads (33%) | called by muse, mutect2, varscan2
- TUBB7P | n.215C>T | RNA (SNP) | VAF 9/59 reads (15%) | catalogued as rs1205852580; called by muse, mutect2, varscan2
- VSIR | c.*3C>T | 3'UTR (SNP) | VAF 22/277 reads (8%) | catalogued as rs371981423; called by muse, mutect2
